HCMI case HCM-BROD-1103-C86 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/df8d98d5-5c5d-425f-9e12-ecaf49a50b9c

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Year of birth: 1963.

Diagnoses (2)
1. Angioimmunoblastic T-cell lymphoma (the primary disease): ICD-O-3 morphology code: 9705/3; ICD-10 code: C86.5; Tissue or organ of origin: Lymph node, NOS; Classification of tumor: primary; Age at diagnosis: 52.1 years (19,037 days); Ann Arbor clinical stage: Stage IV; Prior treatment: Yes.
   Pathology details: Additional pathology findings: Percent follicular component > 10%; Bone marrow malignant cells: Yes; Lymph node involved site: Inguinal.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin Hydrochloride + Etoposide Phosphate + Prednisone + Vincristine Sulfate; Treatment intent type: Neoadjuvant; Days to treatment start: 139 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bendamustine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 215 days; Days to treatment end: 215 days.
   Recorded as not given: neoadjuvant Radiation Therapy, NOS; Surgery, NOS, for initial diagnosis.
2. Angioimmunoblastic T-cell lymphoma: ICD-O-3 morphology code: 9705/3; ICD-10 code: C86.5; Tissue or organ of origin: Lymph node, NOS; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: recurrence; Age at diagnosis: 52.6 years (19,229 days); Days to diagnosis: 192 days.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day 98, day 238.

Molecular and laboratory tests
- JAK2 (Sequencing, NOS): Normal.
- KRAS mutation, nos: Negative.
- MYD88 (Sequencing, NOS): Normal.
- TET2 mutation, nos (Targeted Sequencing): Positive; Pathogenicity: Pathogenic.
- Hemoglobin 7.6 g/dL.
- Platelets 8 ×10³/µL.
- Leukocytes 0.5 ×10³/µL.
- Hematocrit 23%.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 85 kg; BMI: 26.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified.

Family history
- Relative with cancer history: no.

Biospecimens (1 sample)
- Sample HCM-BROD-1103-C86-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 6.
